MMRF case MMRF_1622 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a207ae73-14c1-423a-8ecd-e5ea8b14ba94

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 61 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 61.8 years (22,566 days); Days to last known disease status: 1,163 days (3.2 years); Days to last follow up: 1,163 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 18 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 18 days; Days to treatment end: 638 days (1.7 years).
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 306 days; Days to treatment end: 306 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 307 days; Days to treatment end: 307 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 638 days (1.7 years); Days to treatment end: 990 days (2.7 years).
   Treatment given: Therapeutic agents: Pomalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 638 days (1.7 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -3 (ECOG 0): M Protein 5.49 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 10.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.101 mg/dL; Immunoglobulin G 76.2 g/L; Immunoglobulin A 0.05 g/L; Immunoglobulin M 0.06 g/L; Lactate Dehydrogenase 2.23 µkat/L; Hemoglobin 6.39 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 1.9 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 12.4 g/dL; Glucose 4.95 mmol/L.
- Day 119 (ECOG 0): M Protein 1.85 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.72 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.096 mg/dL; Immunoglobulin G 24.2 g/L; Immunoglobulin A 0.09 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4.1 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 279 ×10⁹/L; Creatinine 82.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 8.5 g/dL; Glucose 6.49 mmol/L.
- Day 225 (ECOG 0): M Protein 0.86 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.887 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.084 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.17 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 273 ×10⁹/L; Creatinine 81.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 260: M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.661 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.073 mg/dL; Immunoglobulin G 9.23 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.36 µg/mL; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 186 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.3 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.
- Day 358 (ECOG 0): M Protein 0.33 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.045 mg/dL; Immunoglobulin G 6.67 g/L; Immunoglobulin A 0.12 g/L; Immunoglobulin M 0.08 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 203 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 3.08 mmol/L.
- Day 435 (ECOG 0): M Protein 0.35 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.082 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.483 mg/dL; Immunoglobulin G 7.47 g/L; Immunoglobulin A 0.14 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 1.42 µg/mL; Lactate Dehydrogenase 3.35 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 84.9 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 7 g/dL; Glucose 6.77 mmol/L.
- Day 526 (ECOG 1): M Protein 0.19 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.086 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.077 mg/dL; Immunoglobulin G 6.31 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.19 µg/mL; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 7 ×10⁹/L; Absolute Neutrophil 4.7 ×10⁹/L; Platelets 164 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 5.61 mmol/L.
- Day 638 (ECOG 0): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.599 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.13 mg/dL; Immunoglobulin G 6.86 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 5.8 µkat/L; Hemoglobin 7.81 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 275 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 7.85 mmol/L; Calcium 2.35 mmol/L; Albumin 37 g/L; Total Protein 6.4 g/dL; Glucose 5.56 mmol/L.
- Day 757 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.821 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.727 mg/dL; Immunoglobulin G 6.02 g/L; Immunoglobulin A 0.52 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 5.2 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 244 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.1 g/dL; Glucose 7.76 mmol/L.
- Day 855 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.746 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.882 mg/dL; Immunoglobulin G 9.56 g/L; Immunoglobulin A 0.59 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 7.82 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 103 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.23 mmol/L; Albumin 34 g/L; Total Protein 6.1 g/dL; Glucose 4.9 mmol/L.
- Day 981 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.723 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.768 mg/dL; Immunoglobulin G 5.65 g/L; Immunoglobulin A 0.58 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.48 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 215 ×10⁹/L; Creatinine 107 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 5.83 mmol/L.
- Day 1,044 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.21 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 6.9 g/L; Immunoglobulin A 0.81 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 3.55 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 1.7 ×10⁹/L; Platelets 246 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.28 mmol/L; Albumin 39 g/L; Total Protein 6.4 g/dL; Glucose 5.45 mmol/L.
- Day 1,121 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.919 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.887 mg/dL; Immunoglobulin G 9.1 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.13 g/L; Lactate Dehydrogenase 7.32 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.26 ×10⁹/L; Platelets 179 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 6.7 g/dL; Glucose 4.79 mmol/L.
- Day 1,163 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.934 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.915 mg/dL; Immunoglobulin G 9.89 g/L; Immunoglobulin A 0.72 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 3.88 µkat/L; Hemoglobin 8.18 mmol/L; Leukocytes 6.1 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 38 g/L; Total Protein 6.4 g/dL; Glucose 5.78 mmol/L.

Other clinical attributes
- Day -3: Weight: 81 kg; Height: 182 cm.

Biospecimens (2 samples)
- Sample MMRF_1622_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -3 days.
- Sample MMRF_1622_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -3 days.
